Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A7WD, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A7WD-01A (Primary Tumor).

[page 1 of 2]
---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

- A. Soft tissue, leg, right, excision:
High grade leiomyosarcoma, 9 cm, margin not involved (0.1 cm from the deep margin).
- B. Soft tissue, additional lower margins, excision:
Benign fibroadipose tissue and skeletal muscle.
- C. Soft tissue, additional deep margin, excision:
Benign fibroadipose tissue and skeletal muscle.

Comment

Date reported:

Pathologist (Electronic Signature)

HISTORY

diagnosed with high grade leiomyosarcoma of right leg.

TISSUE SUBMITTED

- A. Right leg sarcoma long stitch superior short stitch inferior two stitch anterior
- B. Additional lower margin stitch marks true margin
- C. Additional deep margin

GROSS

A. Received fresh in a container labeled with the patient's name, hospital number and "Right leg sarcoma long stitch superior short stitch inferior two stitch anterior" is a 12.0 x 7.0 x 5.0 cm ovoid skin ellipse and subcutaneous tissue excision. A long stitch denotes superior, a short stitch inferior, and double stitch anterior. The long stitch is redesignated as 12 o'clock, the short stitch as 6 o'clock, and the double stitch as 9 o'clock. The 12 to 3 to 6 o'clock margin is inked blue, the 6 to 9 to 12 o'clock margin is inked green, and the deep margin is inked black. Sectioning reveals an 8.0 x 6.0 x 3.8 cm grey-tan, multinodular, solid mass with central hemorrhage and necrosis, <0.1 cm from the deep margin, 1.0 cm from the 6 o'clock margin, 1.2 cm from the 9 o'clock margin, 1.8 cm from the 3 o'clock margin, and 3.1 cm from the 12 o'clock margin. Representative sections submitted as follows: A1, nearest 12 o'clock margin; A2, tumor with nearest 3 o'clock margin; A3, tumor with nearest 6 o'clock margin; A4, tumor with nearest 9 o'clock margin; A5, tumor with nearest deep margin; A6, representative section of tumor with hemorrhagic and necrotic foci and overlying skin. A photograph is taken for the file and emailed to the surgeon. B. Received in formalin in a container labeled with the patient's name, hospital number and "Additional lower margin stitch marks true margin" is a 1.5 x 1.5 x 1.3 cm red-tan to yellow soft tissue fragment. A stitch denotes the new margin and this area is inked blue. The remainder of the specimen is inked green. The specimen is serially sectioned perpendicular to the new margin and submitted in B1. C. Received in formalin in a container labeled with the patient's name, hospital number and "Additional deep margin" is a 1.5 cm in greatest dimension yellow-pink to red soft tissue fragment. Entirely submitted in C1.

MICROSCOPIC

A-C. Microscopic examination performed and supports the diagnosis.

I have personally reviewed the slides and report for this case.

IID-0-3

Leiomyosarcoma NOS
8890/3

Site Leg NOS
C49.2

9/10/10/13

[page 2 of 2]
--- SUPPLEMENTAL REPORT--- (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

SUPPL REPORT

The purpose of this amended report is to insert the cancer synoptic and AJCC staging forms. The diagnosis remains otherwise unchanged.

Tumor microscopic description: Long, intersecting fascicles of spindle shaped tumor cells with nuclear hyperchromasia.

pleomorphism and Histologic type: Leiomyosarcoma.

Histologic grade: High grade.

Mitotic rate (per 10 hpf @ 40X): >20 mitotic figures.

Extent of necrosis: Multifocal necrosis present (<50%).

Vascular invasion: Not identified.

Inflammatory infiltrate: Not identified.

Site and depth: Right thigh, Subcutaneous

Maximal dimension: 8.0 cm.

Minimal distance(s) to resection margins: 0.1 cm from nearest (deep) resection margin

Character of lesional margin: There is a fascial plane defining the deep margin.

Evidence of pre-existing benign lesion: Not identified.

Lymph nodes: Not applicable.

DEFINITIONS

Pathologic Primary Tumor (T)

XX T2a Superficial tumor (1)

Regional Lymph Nodes (N)

X NX Regional lymph nodes cannot be assessed

The pathologic stage based on available pathologic material is: T2A, Nx

The optimal tissue block for molecular studies on neoplasm is A6

Comment

Date reported:

Pathologist (Electronic Signature)

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

--- SUPPLEMENTAL REPORT--- (Order

- Lab and Collection Information

Result History

--- SUPPLEMENTAL REPORT--- (Order #

Order Result History Report

Result Entered By

Lab Information

Source: NCI Genomic Data Commons file 5ca7c745-2f08-47ea-8f94-a30bbcc87c57 (TCGA-X6-A7WD.977C0F13-A474-4105-AD96-AD0CCD1D29F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).